Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADA, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADA-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

Q2 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Laparoscopic wedge resection

Cholecystectomy

Organ: Liver (7.0 x 4.5 x 3.5 cm, 37.0 gm)

Gallbladder (11.0 cm in length, 5.0 cm in diameter)

Lesion: Solid mass of hepatic parenchyme

Size: 4.0 x 3.0 x 3.0 cm

Cut surface: Well-demarcated, yellowish tan, solid and firm mass

Gross type: Multinodular confluent

Extent: Confined to the hepatic parenchyme

Resection margin: Not involved, grossly (safety margin: 0.5 cm)

Remaining parenchyme: Unremarkable

[Gallbladder]

Serosal surface: Yellowish green and smooth

Mucosal surface: Greenish yellow and velvety

Wall: 0.2 cm in thickness

Stone: Single, friable and black (3.0 x 2.5 x 1.5 cm)

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, tumor mass of liver x 4

RM, tumor with resection margin x 1

L, nontumorous liver parenchyme x 1

GB, gallbladder x 1

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Edmondson-steiner grade

The worst differentiation III

The major differentiation III

Histologic type: Trabecular, nesting

Cell type: Hepatic

Fatty change: Yes

Fibrous capsule formation: Yes

Capsular infiltration: Yes

[page 2 of 2]
Septum formation: Yes
Surgical resection margin invasion: Yes
Serosal invasion: Yes
Portal vein invasion: Yes
Vascular invasion: Yes
Bile duct invasion: No
Remaining liver parenchyme: Chronic hepatitis, HBV associated

NOT reported. Gross:

cervix, smear, inflammation

Cervix, smear, suggestive of, bacterial vaginosis

Large intestine, ascending colon, scopic, tubular adenoma, high grade, dysplasia

Large intestine, transverse colon, scopic, tubular adenoma, low grade, dysplasia

Large intestine, transverse colon, scopic, chronic colitis

Large intestine, splenic flexure, scopic, tubular adenoma, low grade, dysplasia

liver, resection, hepatocellular carcinoma

T56000, P17, M81703

gallbladder, ectomy, chronic cholecystitis, cholelithiasis

T57000, P10, M43005, M30011

DIAGNOSIS:

Liver, segment 5, laparoscopic wedge resection:
Hepatocellular carcinoma

Gallbladder, cholecystectomy:
Chronic cholecystitis
Cholelithiasis

Suggestion :

Source: NCI Genomic Data Commons file 1338d1b1-4ca1-4aca-addf-70690a22476c (TCGA-DD-AADA.624DA15E-ADC6-4F09-9DCB-3B4C42F3B453.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).